Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8261, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8261-01A (Primary Tumor).

[page 1 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

PROSTATE, RADICAL PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 3+4=7.
- Tumor is 1.7cm in greatest dimension on slide.
- Tumor involves both left and right lobes of prostate, posteriolaterally.
- 20% of sampled tissue involved by tumor.
- No extraprostatic extension is identified.
- Seminal vesicles not involved by tumor.
- MARGINS: NEGATIVE.
- Closest margin: Radial, at 0.2 cm from tumor.
- Proximal and distal urethral margins are negative for tumor.
- Vas deferentia margins negative for tumor.
- LYMPH NODES: NOT IDENTIFIED.
- HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.

PATHOLOGIC TUMOR STAGING DESCRIPTORS:

Type and grade: Prostatic adenocarcinoma, Gleason grade 3+4=7.

Primary tumor: pT2c.

Regional lymph nodes: pNX.

Distant metastasis: pMX.

Margin status: R0.

Pathologic stage: IIb.

Lymphovascular invasion: Not identified.

Perineural invasion: Not identified.

Prostate Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 3]
Procedure:	Radical prostatectomy.
Specimen type:	Prostate.
Prostate size/weight:	2.5 x 4.8 x 3.9 cm. 59 g.
Tumor Features:	
Tumor site:	Left and right lobes of prostate.
Tumor size:	1.7 cm in greatest slide dimension.
Tumor quantification:	20% of sampled tissue.
Histologic type:	Prostatic adenocarcinoma.
Histologic grade (Gleason pattern):	
Primary pattern:	3.
Secondary pattern:	4.
Tertiary pattern:	N/A.
Total Gleason score:	7.
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.
Extraprostatic extension:	Not identified.
Seminal vesicle invasion:	Not identified.
Treatment effect:	Not identified.
Lymph Nodes:	None identified.
Margin Evaluation:	
Distance to closest margin:	0.2 cm (radial margin).
Other margins:	Proximal and distal urethral margins negative for tumor; vas deferentia margins negative for tumor.
Pathologic tumor staging descriptors:	
Primary tumor (pT):	2c.
Regional lymph nodes (pN):	pNX.
Distant metastasis (pM):	pMX.
Margin status (R):	R0.
Pathologic stage:	IIB.
Additional findings:	High-grade prostatic intraepithelial neoplasia.
Comment:	N/A.

[page 3 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Prostatectomy

Clinical History/Operative Dx:

Prostate cancer

Gross Description:

Single specimen designated prostate. Initially received in a fresh state for [REDACTED], is a 59 gram radical prostatectomy, 2.5 cm apex to base, 4.8 cm across and 3.9 cm posterior-anterior. The right and left vas deferens are 3.3 x 0.4 cm and 3.0 x 0.4 cm each, respectively. The right and left seminal vesicles are 4.3 x 2.0 cm and 3.6 x 2.0 cm each, respectively. Initial sections through the seminal vesicles demonstrates a rubbery light pink and tan honeycomb cut surface without gross tumor involvement. Radial margin of prostate demonstrates slightly shaggy, deep red-tan appearance, now differentially inked as follows: the right anterior-lateral is marked blue, the left anterior-lateral marked orange, and the posterior surface marked black. The specimen is serially sectioned apex to base to reveal a poorly demarcated to pink-gray lesion in the right posterior aspect of the prostate, within 1.0 cm of the apex, suspicious for malignancy. Representative portion of this lesion is submitted for [REDACTED] as well as representation of the left seminal vesicles. This lesion measures 1.0 x 0.8 x 0.8 cm and grossly approaches to 0.4 cm of the right posterior prostatic margin (A10-A11). Additional yellow-orange indurated changes are bilaterally present, within 0.3 cm of the apex, with the left anterior-lateral aspect suspicious for malignancy (A14-A15). Representative sections are submitted for microscopic evaluation in a sequential fashion apex toward base.

Cassette summary: A1) right vas deferens margins, seminal vesicles represented, A2) left vas deferens margin, seminal vesicles represented, A3-A4) right and left apex sectioned and submitted, respectively, A5-A6) right and left base sectioned and submitted, respectively, A7-A9) right body of prostate, anterior-lateral, apex toward base, A10-A13) right body of prostate, posterior-lateral, apex toward base, origin of seminal vesicles demonstrated in A13, A14-A16) left body of prostate, anterior-lateral apex toward base, A17-A20) left body of prostate, posterior-lateral apex toward base, origin of seminal vesicles demonstrated in A20. [REDACTED]

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file 92e1a4a7-ed53-46da-be80-c42ec29746bf (TCGA-HC-8261.66690C59-06AE-4D5E-B862-3BE6A11D67FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).